Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A1HW, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A1HW-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History and Impression:

Mass left neck. year-old female S/O 7 month resection for melanoma, left infraclavicular chest. Now with mass left neck.

Specimen(s) Received:

- 1: LEFT NECK DISSECTION
- 2: LEFT NECK SCAR

FINAL DIAGNOSIS

1) LYMPH NODES, LEFT NECK, DISSECTION:

- ONE OF EIGHTEEN LYMPH NODES POSITIVE FOR METASTATIC MELANOMA (1/18)

2) "SCAR", LEFT NECK, EXCISIONAL BIOPSY:

- SKIN WITH SCAR
- NO MALIGNANCY SEEN

1CB-0-3

Melanoma, NOS 8720/3

Site: lymph nodes, NOS C77.9

3/12/11

Pathologist: M.D.

* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description: () M.D. ; () M.D.)

1) Received fresh, labelled with the patient's name, MR# and "left neck dissection", and consists of and unoriented aggregate of yellow lobulated lymph node bearing adipose tissue. There is a previously transected lymph node with orange dye. The specimen measures 7.3 x 4.6 x 1.3 cm. Multiple lymph nodes are dissected out ranging from 0.3 cm up to 2.2 cm. Cassettes 1 and 2 contain bisected lymph nodes, cassette 3-7 multiple possible lymph nodes.

2) Received fresh, labelled with the patient's name, MR# and "left neck scar", and consists of an ellipse of tan-pink wrinkled skin measuring 7.0 x 1.0 cm and excised to a depth of 0.6 cm. The specimen is inked black and representative sections are submitted into one cassette.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Summary of Tissue Submitted for Microscopic Examination

	# Blocks	Designation	Block Detail	
			#	Description
Part 1) LEFT NECK DISSECTION	7	BLN	(2)	Dissected in
		MLN	(5)	Multiple LNs (each own node)
Part 2) LEFT NECK SCAR	1	sk	(1)	(No Description)
Total:			8	

END OF REPORT

Source: NCI Genomic Data Commons file 5be9bbd8-9b1f-4a86-b9a4-3f1400faa7b6 (TCGA-DA-A1HW.B0F2FD1C-03C7-49BF-BD36-EFCC1E205D79.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).